Gene-level copy-number profile of tumor specimen ALCH-B41R-TTP1-A from ALCHEMIST case ALCH-B41R, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 46.9 years (17,145 days).
Specimen ALCH-B41R-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 075ec50a-2f4a-4b61-90d3-3a0fc0daa831.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B41R-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/45a83d51-0c6e-4760-bce1-8fca7380298f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 32; copy number 1: 3,981; copy number 2: 52,510; copy number 3: 941; copy number 4: 518; copy number 5: 193; copy number 6: 158; copy number 7: 22; copy number 8: 8; copy number 9: 37; copy number 11: 2; copy number 21: 1.

Homozygous deletions (total copy number 0; autosomes only): 32 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:47,010,824–47,013,465, 1 gene: NRADDP.
- chr3:129,555,214–129,606,676, 2 genes: PLXND1, RN7SL752P.
- chr5:132,060,655–132,080,133, 3 genes: IL3, CSF2, AC034216.1.
- chr6:3,751,111–3,753,871, 1 gene (within-gene range 0–1): AL391422.4.
- chr9:93,951,627–93,959,140, 2 genes: BARX1, BARX1-DT.
- chr11:1,469,457–1,501,247, 1 gene: MOB2.
- chr14:75,427,716–75,474,111, 1 gene (within-gene range 0–2): JDP2.
- chr14:99,500,190–99,604,207, 1 gene (within-gene range 0–2): CCDC85C.
- chr14:99,583,017–99,583,118, 1 gene: Y_RNA.
- chr15:25,169,337–25,176,913, 5 genes (within-gene range 0–2): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4.
- chr15:42,067,009–42,094,562, 1 gene: PLA2G4D.
- chr15:75,249,232–75,302,965, 7 genes: AC068338.1, NIFKP4, GOLGA6C, RN7SL489P, GOLGA6D, RN7SL327P, DNM1P34.
- chr17:17,494,437–17,496,395, 1 gene: RASD1.
- chr17:17,507,351–17,508,308, 1 gene (within-gene range 0–1): AC020558.2.
- chr19:46,719,511–46,746,994, 3 genes (within-gene range 0–2): STRN4, AC008635.1, Y_RNA.
- chr22:41,909,554–41,914,667, 1 gene: SHISA8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 421 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,671,990–1,674,397, 1 gene, copy number 5 (within-gene range 4–5): AL691432.1.
- chr2:106,207,394–106,208,115, 1 gene, copy number 5: AC092106.1.
- chr2:119,993,199–121,809,962, 38 genes, copy number 5: RPL27P7, EPB41L5, AC012363.1, Y_RNA, MTATP6P26, MTCO3P43, MTND3P10, MTND4LP14, MTND4P26, MTND5P28, TMEM185B, RALB, AC012363.2, INHBB, LINC01101, AC073257.2, AC073257.1, Y_RNA, AC018866.1, GLI2, AC017033.1, Y_RNA, AC067960.1, AC079988.1, TFCP2L1, RPS17P7, CLASP1, AC012447.1, RNU4ATAC, Y_RNA, NIFK-AS1, RPL12P15, AC018737.2, NPM1P32, NIFK, TSN, AC018737.1, LINC01823.
- chr2:126,308,494–126,558,162, 3 genes, copy number 7: AC023347.1, SLC6A14P3, YWHAZP2.
- chr2:127,017,421–127,294,166, 9 genes, copy number 6: RNU7-182P, AC012508.2, AC012508.3, AC012508.1, BIN1, NIFKP9, CYP27C1, WBP11P2, ERCC3.
- chr2:242,087,351–242,088,457, 1 gene, copy number 5: AC093642.2.
- chr8:40,900,016–41,625,001, 17 genes, copy number 6: AC048387.1, RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3.
- chr8:41,653,220–41,896,762, 1 gene, copy number 6 (within-gene range 3–6): ANK1.
- chr8:41,803,349–43,544,057, 58 genes, copy number 5–6: Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19, CHRNB3, AC103843.1, AC103843.2, CHRNA6, THAP1, AC087533.1, RNF170, RN7SL806P, MIR4469, HOOK3, Y_RNA, AC110275.1, FNTA, RNU1-124P, POMK, AC113191.1, HGSNAT, VN1R46P, AC022616.5, AC022616.7, AC022616.3, AC022616.2, AFG3L2P1, AC022616.1, AC022616.4, POTEA, RNU6-104P, AC022616.8, AC022616.6, U3, AC134698.1, AC134698.4, AC134698.3, SNX18P27, AC134698.5, CYP4F44P, AC134698.2.
- chr8:46,549,089–49,229,174, 59 genes, copy number 5–6: HSPA8P13, ASNSP1, AC104576.1, ASNSP4, AC021451.1, TRIM60P15, LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20, AC091163.3, AC091163.1, AC091163.2, MAPK6P4, RN7SKP32, AC120036.1, AC120036.5, RNU6-819P, RPL10AP2, NDUFA5P12, AC120036.3, AC120036.4, ATP6V1G1P2, AC120036.2, IGLV8OR8-1, SPIDR, AC024451.2, AC024451.4, AC024451.1, AC024451.3, RNU6-665P, CEBPD, PRKDC, Y_RNA, AC021236.1, MCM4, RNU6-519P, UBE2V2, AC104989.1, IDI1P2, RNU6-295P, RNA5SP531, RPL29P19, AC041040.1, AC026904.1, AC026904.2, AC022915.2, LINC02599, LINC02847, AC022915.1, AC022915.3, EFCAB1, AC013701.1, SNAI2, AC044893.2, PPDPFL, AC044893.1.
- chr8:90,993,802–91,219,236, 7 genes, copy number 5 (within-gene range 2–5): PIP4P2, AC087439.1, AC087439.2, OTUD6B-AS1, OTUD6B, LRRC69, CPP.
- chr8:100,895,771–101,669,726, 27 genes, copy number 5: RPS26P6, Metazoa_SRP, AC027373.1, YWHAZ, RN7SL685P, FLJ42969, AP003469.2, AP003469.1, RN7SKP249, AP003469.3, ZNNT1, ZNF706, AP001330.4, AP001330.2, LINC02844, AP001330.1, RNU7-67P, AP001330.3, NACA4P, DUXAP2, LINC02845, RN7SL563P, AP001208.1, AP001207.3, GRHL2, AP001207.2, AP001207.1.
- chr8:144,012,280–144,047,114, 1 gene, copy number 6 (within-gene range 2–6): SPATC1.
- chr11:131,004,128–131,004,429, 1 gene, copy number 5: RN7SL167P.
- chr12:67,131,567–70,354,993, 75 genes, copy number 6–9 (broad region; genes not listed).
- chr12:76,721,534–76,879,023, 4 genes, copy number 6 (within-gene range 2–6): RPL7P43, AC093014.1, ZDHHC17, CSRP2.
- chr16:46,789,898–47,162,749, 12 genes, copy number 6–8 (within-gene range 3–8): AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2, DNAJA2, AC018845.3, AC018845.1, AC018845.2, NETO2, ITFG1-AS1, RPL23AP72.
- chr16:48,356,364–48,498,601, 5 genes, copy number 6 (within-gene range 2–6): SIAH1, Metazoa_SRP, AC026470.3, AC026470.1, MOCS1P1.
- chr16:59,709,993–60,523,250, 7 genes, copy number 5: APOOP5, LINC02141, AC009094.1, AC009081.2, AC018554.1, NPAP1L, AC009081.1.
- chr16:63,180,610–63,936,906, 8 genes, copy number 6: UBE2FP2, AC138305.1, RPS15AP34, AC138305.2, AC138305.3, AC018846.1, LINC02165, AC092337.1.
- chr16:65,233,056–65,646,947, 4 genes, copy number 7 (within-gene range 4–7): AC009055.1, LINC00922, AC092138.2, AC092138.1.
- chr16:68,530,090–68,576,072, 1 gene, copy number 6 (within-gene range 4–6): ZFP90.
- chr16:68,573,782–68,835,541, 12 genes, copy number 6: AC126773.3, AC126773.6, AC126773.1, AC126773.2, CDH3, AC126773.4, AC126773.5, HSPE1P5, CDH1, RNA5SP429, AC099314.1, FTLP14.
- chr16:69,105,653–70,686,053, 65 genes, copy number 6 (broad region; genes not listed).
- chr16:71,833,787–71,835,932, 1 gene, copy number 5: AC010653.1.
- chr21:43,446,601–43,479,534, 3 genes, copy number 11–21: LINC00319, LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 3,936. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
